Surgical pathology report (de-identified scan), TCGA case TCGA-29-1784, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1784-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1784

Surg Path

CLINICAL HISTORY:

Ovarian cyst [REDACTED] 11 x 9 x 6 cm left adnexal mass per Ebrowser. CA125 increased T9 at 888 also per Ebrowser.

GROSS EXAMINATION:

A. "Right tube and ovary (A1)", received fresh and placed in formalin on [REDACTED] is a 304 gram, 12 x 9 x 5 cm well-encapsulated ovarian tumor. The cut surface is pink-tan. The tumor, which is largely solid (A1 Frozen section; remnant in A1, additional blocks A2-7), contains cysts filled with serous fluid. There only residual normal ovarian parenchyma is a single corpus albicans (A8). The 1.7 cm long, 0.4 cm in diameter fallopian tube is unremarkable (A9).

B. "Left tube and ovary", received in formalin is a 3 x 1.5 x 1 cm pink-tan, lobulated ovary, which upon sectioning shows a 1.6 x 1 cm intraparenchymal, tan-yellow, solid mass that expands but does not penetrate the capsule. The remainder of the parenchyma is grossly unremarkable.

Attached to the ovary is a 3.4 cm long x 0.4 cm in diameter grossly unremarkable fimbriated fallopian tube and soft tissue. Representative sections of ovary are submitted in blocks B1-2 and fallopian tube in B3.

C. "Uterus and cervix", received in formalin is a 73 gram, 7.6 x 6.1 x 3.4 cm uterus. The serosa is pink-tan, erythematous, and contains a 1.3 x 1 x 0.5 cm subserosal nodule. The ectocervix (4 x 3.7 cm) is pink-tan with a patent 1 cm os. The endometrial cavity (1.5 x 3.5 cm) is lined by a 0.2 cm red, smooth endometrium overlying a 2 cm thick myometrium. The myometrium has two tan-white, homogeneous, whorled nodules ranging from 1 cm to 1.5 cm in greatest dimension.

BLOCK SUMMARY:

- C1- anterior cervix
- C2- anterior endomyometrium with nodule
- C3- posterior cervix
- C4- endomyometrium with nodule
- C5- subserosal nodule

D. "Omentum", received in formalin is a 16 x 12 x 2 cm fragment of unremarkable yellow lobulated adipose tissue represented in block D1.

E. "Right peritoneal biopsy of polyp", received fresh in formalin [REDACTED] is a 3.8 x 1 x 0.6 cm fragment of tan, hemorrhagic soft tissue is submitted entirely in block E1.

F. "Right paraaortic lymph node", received fresh and placed in formalin on [REDACTED] is a 7.3 x 3 x 2 cm fragment of yellow, lobulated adipose tissue, is dissected for lymph nodes. One lymph node candidate is grossly identified (3.8 x 1.9 x 0.6 cm), and has a yellow-tan, soft cut surface. The lymph node candidate is serially sectioned and submitted entirely in blocks F1-6.

G. "Right common iliac lymph node", received in formalin is a 4 x 2 x 1.1 cm fragment of yellow lobulated adipose tissue, dissected for lymph nodes. One lymph node candidate is grossly identified (2.5 x 1.2 x 0.7 cm), is bisected and submitted entirely in block G1, and the remainder of the adipose tissue in block G2.

H. "Right gutter peritoneum", received in formalin is a 2.4 x 1 x 0.8 cm

[page 2 of 2]
fragment of yellow-tan soft tissue and is submitted entirely in block H1.

I. "Right external node", received fresh and placed in formalin on [REDACTED]
[REDACTED] is a 4.4 x 2.5 x 1.3 cm fragment of yellow, lobulated adipose tissue, is dissected for lymph nodes. One lymph node candidate is grossly identified (3.1 x 0.9 x 0.1 cm), is bisected and submitted entirely in block I1 and the remainder of the adipose tissue in blocks and I2-3.

TCGA-29-1784

INTRA OPERATIVE CONSULTATION:

A. "Right tube and ovary":

AF1- (solid portion)- malignant carcinoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY, OOPHORECTOMY & LYMPHADENECTOMY

PATHOLOGIC STAGE

FIGO 3B

[REDACTED] pT1B pN1 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "RIGHT OVARY":

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 3

TUMOR SIZE: 12 X 9 X 5 CM.

WEIGHT: 304 GRAMS

SEROSA: INVOLVED

WITH METASTATIC/IMPLANTED TUMOR, INVOLVING THE FOLLOWING SPECIMENS

B. LEFT OVARY: 1.6 CM METASTASIS

F. RIGHT PARAAORTIC LYMPH NODE: ONE OF ONE LYMPH NODE IS FILLED ENTIRELY WITH CANCER (3.8 X 1.9 X 0.6 CM).

SPECIMENS FREE OF TUMOR

A. RIGHT FALLOPIAN TUBE

B. LEFT FALLOPIAN TUBE

C. UTERUS, 73 GRAMS

ENDOMETRIUM: QUIESCENT

MYOMETRIUM: LEIOMYOMA, SMALL

CERVIX: NO PATHOLOGIC DIAGNOSIS.

SEROSA: NO PATHOLOGIC DIAGNOSIS

D. OMENTUM

E. RIGHT PERITONEAL BIOPSY OF POLYP

G. RIGHT COMMON ILIAC LYMPH NODES: NO TUMOR IN 2 LYMPH NODES (0/2).

H. RIGHT GUTTER PERITONEUM: NO PATHOLOGIC DIAGNOSIS.

I. RIGHT EXTERNAL ILIAC LYMPH NODE: NO TUMOR IN 1 LYMPH NODE (0/1).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 46414333-fa5c-4ef5-8171-124a01c32b09 (TCGA-29-1784.E4614E5D-EB1F-4AC7-A17F-105936745E80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).